Somatic mutation profile of tumor specimen TCGA-AL-3467-01A (aliquot TCGA-AL-3467-01A-01D-1252-08) from TCGA case TCGA-AL-3467, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 54.2 years (19,783 days).
Specimen TCGA-AL-3467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0fc29a2-3714-4f73-a8a1-79ab7ee45ea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-3467-10A (Blood Derived Normal), aliquot TCGA-AL-3467-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52272bbc-7629-4cd2-a030-5aec91938d4c

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH8 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100181543; called by muse, mutect2, varscan2
- CPNE6 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.122); catalogued as COSV53744396; called by muse, mutect2, varscan2
- PRRC1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV56990317; called by muse, mutect2
- SNX13 | c.2564A>G p.D855G | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1359666800; called by muse, mutect2
- AMD1 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CELSR1 | c.6443T>C p.L2148P | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2
- CORO1B | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- GCOM1 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2
- LARGE2 | c.1121A>C p.E374A | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PRRC2C | c.7477C>T p.H2493Y (on ENST00000367742; = p.H2491Y on NM_015172.4) | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYND15 | c.885del p.T296Hfs*30 | Frame Shift Del (DEL) | VAF 70/214 reads (33%) | called by mutect2, pindel, varscan2
- CDH8 | c.660T>G p.P220= | Silent (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- GOLGA8G | c.1146G>A p.E382= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
